Gene-level copy-number profile of tumor specimen TCGA-CD-8528-01A from TCGA case TCGA-CD-8528, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 43.8 years (15,986 days).
Specimen TCGA-CD-8528-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1bddd1b6-0409-488f-9b26-8e7ecb7903a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8528-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85533484-5e31-4365-b19a-f9f1e918935a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 22; copy number 2: 11,596; copy number 3: 21,623; copy number 4: 21,997; copy number 5: 2,617; copy number 6: 1,574; copy number 7: 141; copy number 10: 54; copy number 22: 2; copy number 27: 20; copy number 38: 53; copy number 40: 5; copy number 44: 57; copy number 49: 6; copy number 54: 1; copy number 61: 2; copy number 64: 17; copy number 68: 15; copy number 76: 8; copy number 89: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8528-01A-11D-2338-01): tumor purity 0.55, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 246 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,271,634–106,788,148, 17 genes, copy number 64: U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587.
- chr7:54,933,699–55,260,256, 6 genes, copy number 49: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:57,200,825–57,275,197, 5 genes, copy number 40: GUSBP12, AC099654.1, RNU7-157P, AC099654.12, AC099654.3.
- chr7:114,086,327–117,230,176, 54 genes, copy number 10 (within-gene range 2–10): FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4.
- chr8:126,556,323–127,419,050, 1 gene, copy number 68 (within-gene range 5–68): PCAT1.
- chr8:127,072,694–127,742,951, 12 genes, copy number 68: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,890,720, 2 genes, copy number 68: MIR1204, AC084123.1.
- chr15:51,414,097–51,498,833, 1 gene, copy number 89: AC066613.2.
- chr15:51,455,268–51,460,582, 1 gene, copy number 89: AC066613.1.
- chr15:72,284,727–72,686,182, 20 genes, copy number 27 (within-gene range 5–27): AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1.
- chr15:82,113,384–82,334,609, 6 genes, copy number 61–89 (within-gene range 5–89): AC026956.2, EFL1, RNU1-77P, AC026624.1, SAXO2, ADAMTS7P1.
- chr15:98,646,951–99,135,593, 11 genes, copy number 22–76: IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2.
- chr19:8,695,721–9,435,571, 36 genes, copy number 38 (within-gene range 3–38): AC243312.1, ACTL9, OR2Z1, RPL23AP78, AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16, BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266.
- chr19:39,083,913–39,385,710, 17 genes, copy number 38: ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P.
- chr19:43,827,321–44,821,421, 57 genes, copy number 44: ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, AC138470.2, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
